Somatic mutation profile of tumor specimen TCGA-21-1083-01A (aliquot TCGA-21-1083-01A-01W-0782-08) from TCGA case TCGA-21-1083, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 75.9 years (27,708 days).
Specimen TCGA-21-1083-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8d64bbf-5ab3-460c-b738-79e48874e881.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-21-1083-11A (Solid Tissue Normal), aliquot TCGA-21-1083-11A-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3e3789a-f1d6-4a91-a9f6-06e337e3306f

The open-access MAF lists 777 somatic variants for this specimen: 612 protein-altering or splice-affecting, 146 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 532, Silent 146, Nonsense Mutation 39, Frame Shift Del 19, Splice Site 12, Intron 8, RNA 7, Frame Shift Ins 4, Splice Region 3, 5'Flank 3, Translation Start Site 2, 3'UTR 1.

Variants (750 of 777; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR2 | c.1975A>G p.K659E | Missense Mutation (SNP) | VAF 133/232 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1057519795, COSV60638890; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 42/181 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM981671, CM993670, COSV64293729, COSV64297280; called by muse, mutect2, varscan2
- TP53 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 254/451 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.10846G>T p.A3616S | Missense Mutation (SNP) | VAF 100/196 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.385); catalogued as COSV71292577; called by muse, mutect2, varscan2
- ABCG8 | c.220C>A p.P74T | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs373610655; called by muse, mutect2, varscan2
- ABRAXAS2 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 70/195 reads (36%) | catalogued as rs1322334175; called by muse, mutect2, varscan2
- ACACB | c.1333G>C p.E445Q | Missense Mutation (SNP) | VAF 418/1267 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.61); catalogued as COSV58141287; called by muse, mutect2, varscan2
- ACP4 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1328817906; called by muse, mutect2
- ADAM18 | c.1231G>T p.E411* | Nonsense Mutation (SNP) | VAF 17/59 reads (29%) | catalogued as COSV55855051; called by muse, mutect2, varscan2
- ADAMTS12 | c.2620C>G p.Q874E | Missense Mutation (SNP) | VAF 101/281 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV61270116; called by muse, mutect2, varscan2
- ADCY10 | c.2224A>T p.K742* | Nonsense Mutation (SNP) | VAF 140/364 reads (38%) | catalogued as COSV100896614, COSV63240116; called by muse, mutect2, varscan2
- ADD3 | c.1994C>T p.P665L (on ENST00000356080 / NM_001320591.2; = p.P633L on NM_001121.4) | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.103); catalogued as rs948617109; called by muse, mutect2
- ADGRB3 | c.4376G>T p.S1459I | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99484119; called by muse, mutect2, varscan2
- ADGRL3 | c.2483C>A p.A828D (on ENST00000506720 / NM_001322402.2; = p.A760D on NM_015236.6) | Missense Mutation (SNP) | VAF 362/688 reads (53%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as COSV72229455, COSV72230768; called by muse, varscan2
- ADNP2 | c.242C>G p.S81C | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1490543133, COSV51536849; called by muse, mutect2, varscan2
- AGAP6 | c.1233G>T p.W411C (on ENST00000374056 / NM_001365867.1; = p.W434C on NM_001077665.2) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100929041; called by mutect2, varscan2
- AHCTF1 | c.3131G>A p.R1044Q (on ENST00000366508; = p.R1018Q on NM_015446.5) | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as rs138283580; called by muse, mutect2, varscan2
- ALK | c.1652G>A p.R551Q | Missense Mutation (SNP) | VAF 135/371 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as rs374136388, COSV66564829; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMPD1 | c.1769G>T p.S590I | Missense Mutation (SNP) | VAF 118/238 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.281); catalogued as rs1189693289; called by muse, mutect2, varscan2
- ANK1 | c.890C>A p.P297Q | Missense Mutation (SNP) | VAF 38/255 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.228); catalogued as COSV55872662; called by muse, mutect2, varscan2
- ANO4 | c.1311G>C p.W437C (on ENST00000392977 / NM_001286615.2; = p.W402C on NM_178826.4) | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100153592, COSV54614380; called by muse, mutect2, varscan2
- AOX1 | c.1611G>A p.M537I | Missense Mutation (SNP) | VAF 74/176 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV101022029; called by muse, mutect2, varscan2
- ARFGAP1 | c.343-2A>T p.X115_splice | Splice Site (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100796633; called by muse, mutect2, varscan2
- ARMC4 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99518237; called by muse, varscan2
- ARRDC2 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0.428); catalogued as COSV55846075; called by muse, mutect2
- ARSH | c.673C>T p.L225F | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV66962659; called by muse, mutect2, varscan2
- BCO1 | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 142/249 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99257860; called by muse, mutect2, varscan2
- BRCA1 | c.2963C>G p.S988* | Nonsense Mutation (SNP) | VAF 77/261 reads (30%) | catalogued as CM030788, COSV58794810; called by muse, mutect2, varscan2
- BRCA1 | c.2666C>G p.S889C | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58801122; called by muse, mutect2, varscan2
- BRD2 | c.1663A>G p.K555E | Missense Mutation (SNP) | VAF 70/102 reads (69%) | SIFT tolerated (0.54); PolyPhen benign (0.048); catalogued as rs1218388178; called by muse, mutect2, varscan2
- C7 | c.1487C>A p.A496E | Missense Mutation (SNP) | VAF 55/380 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.617); catalogued as rs956474428; called by muse, mutect2, varscan2
- CACNA1E | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.13); catalogued as COSV100703618; called by muse, mutect2
- CACNA2D2 | c.1296C>A p.N432K | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV56561534; called by muse, mutect2, varscan2
- CACNG3 | c.932G>C p.R311P | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50068726, COSV50070085, COSV50078325; called by muse, mutect2, varscan2
- CAMTA1 | c.2212G>C p.G738R | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.068); catalogued as COSV100349098, COSV100350713; called by muse, mutect2, varscan2
- CANX | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 288/928 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.079); catalogued as COSV56004337; called by muse, mutect2, varscan2
- CD300A | c.628+1G>T p.X210_splice | Splice Site (SNP) | VAF 58/142 reads (41%) | catalogued as COSV100177833; called by muse, varscan2
- CES5A | c.92C>A p.P31Q | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs137860220; called by muse, mutect2, varscan2
- CFAP221 | c.877C>T p.R293* | Nonsense Mutation (SNP) | VAF 71/183 reads (39%) | catalogued as rs752357355, COSV54654594, COSV99733007; called by muse, mutect2, varscan2
- CFH | c.1985G>C p.R662T | Missense Mutation (SNP) | VAF 168/410 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.258); catalogued as COSV66411243; called by muse, mutect2, varscan2
- CFHR5 | c.790+1G>A p.X264_splice | Splice Site (SNP) | VAF 20/46 reads (43%) | catalogued as COSV99887989; called by muse, mutect2
- CHAT | c.1643G>A p.R548Q | Missense Mutation (SNP) | VAF 112/343 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as rs141881680, COSV60334982; called by muse, mutect2, varscan2
- CLCN5 | c.805G>A p.V269I | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as rs781834071; called by muse, mutect2, varscan2
- CLINT1 | c.1726A>T p.M576L | Missense Mutation (SNP) | VAF 86/240 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs758692113; called by muse, mutect2, varscan2
- CNOT1 | c.2345G>T p.G782V | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.061); catalogued as COSV104395768; called by muse, mutect2, varscan2
- COL24A1 | c.4267G>A p.G1423S | Missense Mutation (SNP) | VAF 80/197 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1303133058; called by muse, mutect2, varscan2
- COL2A1 | c.2068G>T p.G690* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as CM152036; called by muse, mutect2, varscan2
- COL3A1 | c.1789G>T p.G597C | Missense Mutation (SNP) | VAF 113/349 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104394805; called by muse, mutect2, varscan2
- COL6A6 | c.4523G>T p.R1508L | Missense Mutation (SNP) | VAF 68/329 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.141); catalogued as COSV100650050, COSV62038152; called by muse, mutect2, varscan2
- CREB3L2 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 10/34 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs1332023192; called by muse, mutect2, varscan2
- CRIM1 | c.805C>G p.P269A | Missense Mutation (SNP) | VAF 87/442 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs369675156, COSV54874356; called by muse, mutect2, varscan2
- CSMD1 | c.332T>C p.I111T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.202); catalogued as rs1245504019; called by muse, mutect2, varscan2
- CSMD3 | c.10529G>A p.R3510K (on ENST00000297405 / NM_001363185.1; = p.R3341K on NM_052900.3) | Missense Mutation (SNP) | VAF 128/221 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764049965; called by muse, mutect2, varscan2
- CSMD3 | c.4580C>A p.A1527E (on ENST00000297405 / NM_001363185.1; = p.A1423E on NM_052900.3) | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV52334489; called by muse, mutect2, varscan2
- CSMD3 | c.3916C>G p.L1306V (on ENST00000297405 / NM_001363185.1; = p.L1202V on NM_052900.3) | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs936727664, COSV99848959; called by muse, mutect2, varscan2
- CTNND2 | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.036); catalogued as COSV58873258; called by muse, varscan2
- CYLC2 | c.729G>C p.K243N | Missense Mutation (SNP) | VAF 77/134 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV66338398, COSV66339743; called by muse, mutect2, varscan2
- DCAF4L2 | c.994G>T p.V332L | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60479126, COSV60479633; called by muse, mutect2, varscan2
- DDX41 | c.434+1G>A p.X145_splice | Splice Site (SNP) | VAF 17/43 reads (40%) | catalogued as COSV100286394; called by muse, mutect2, varscan2
- DEFB112 | c.90T>A p.S30R | Missense Mutation (SNP) | VAF 71/247 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as rs1012164398, COSV100452168; called by muse, mutect2, varscan2
- DEFB125 | c.142C>T p.L48F | Missense Mutation (SNP) | VAF 30/496 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66703291; called by muse, mutect2
- DGKG | c.121C>A p.L41I | Missense Mutation (SNP) | VAF 113/414 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV53972592; called by muse, mutect2, varscan2
- DGKK | c.1331G>T p.R444L | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.72); PolyPhen benign (0.009); catalogued as COSV101053008; called by muse, mutect2, varscan2
- DIS3 | c.1101+1G>A p.X367_splice | Splice Site (SNP) | VAF 42/114 reads (37%) | catalogued as rs776543561, COSV100899825; called by muse, mutect2, varscan2
- DSC1 | c.2317G>T p.G773* | Nonsense Mutation (SNP) | VAF 92/428 reads (21%) | catalogued as COSV57145841; called by muse, mutect2, varscan2
- DTWD2 | c.316A>T p.K106* | Nonsense Mutation (SNP) | VAF 24/85 reads (28%) | catalogued as COSV100407012; called by muse, mutect2, varscan2
- EP400 | c.4417G>T p.A1473S | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.35); catalogued as COSV100200717; called by muse, mutect2
- EPHA10 | c.2776G>T p.D926Y | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100361123; called by muse, mutect2
- ERAP2 | c.1582C>G p.L528V | Missense Mutation (SNP) | VAF 194/379 reads (51%) | SIFT tolerated (0.56); PolyPhen benign (0.045); catalogued as COSV65941049; called by muse, mutect2, varscan2
- ERBB4 | c.2139G>T p.L713F | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV53524670, COSV99631378; called by muse, mutect2, varscan2
- EXOC2 | c.2436+1G>T p.X812_splice | Splice Site (SNP) | VAF 20/111 reads (18%) | catalogued as COSV100032868; called by muse, mutect2, varscan2
- EXOC8 | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV50478912; called by muse, mutect2, varscan2
- F13B | c.1262T>A p.V421E | Missense Mutation (SNP) | VAF 90/275 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM103611; called by muse, mutect2, varscan2
- FAM13C | c.1555C>T p.R519* | Nonsense Mutation (SNP) | VAF 138/325 reads (42%) | catalogued as rs1402392418, COSV53255118; called by muse, mutect2, varscan2
- FCGR2C | c.582C>G p.H194Q | Missense Mutation (SNP) | VAF 125/256 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100912528; called by muse, mutect2, varscan2
- FLG | c.8773G>A p.D2925N | Missense Mutation (SNP) | VAF 46/279 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); catalogued as COSV100910564; called by muse, mutect2, varscan2
- FREM2 | c.6253G>A p.D2085N | Missense Mutation (SNP) | VAF 44/213 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1475945300; called by muse, mutect2, varscan2
- GABRG2 | c.104C>G p.P35R | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.062); catalogued as COSV99054935; called by muse, mutect2, varscan2
- GAD2 | c.1070A>G p.Y357C | Missense Mutation (SNP) | VAF 93/272 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs761992421; called by muse, mutect2, varscan2
- GALC | c.1312C>T p.L438F | Missense Mutation (SNP) | VAF 33/51 reads (65%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as COSV54323724; called by muse, mutect2, varscan2
- GBA3 | c.718C>A p.Q240K | Missense Mutation (SNP) | VAF 130/320 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV101545473, COSV72438612; called by muse, mutect2, varscan2
- GGH | c.261C>G p.F87L | Missense Mutation (SNP) | VAF 169/274 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as rs538903371; called by muse, mutect2, varscan2
- GPC5 | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 5/56 reads (9%) | catalogued as COSV65582016; called by mutect2, varscan2
- GPX5 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 376/780 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs1343748604; called by muse, mutect2, varscan2
- HGF | c.1851G>T p.W617C | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55951307; called by muse, mutect2, varscan2
- HK2 | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 308/750 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs773701506; called by muse, mutect2, varscan2
- HOXC10 | c.10C>G p.P4A | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs747352685, COSV57726960; called by muse, mutect2, varscan2
- IFNA4 | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs200551386, COSV101427011, COSV70179858; called by muse, mutect2, varscan2
- IFT81 | c.1426G>C p.D476H | Missense Mutation (SNP) | VAF 161/415 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99655660; called by muse, mutect2, varscan2
- IGKV2D-29 | c.160G>T p.G54* | Nonsense Mutation (SNP) | VAF 48/98 reads (49%) | catalogued as COSV101534374; called by muse, varscan2
- IGKV2D-29 | c.211C>A p.L71I | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.35); catalogued as rs1448588272; called by muse, varscan2
- ITIH5 | c.1544C>A p.A515E | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53668672; called by muse, mutect2, varscan2
- ITPRIPL2 | c.1217T>C p.V406A | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs1400434352; called by mutect2, varscan2
- KCNG1 | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1457752627, COSV65369000; called by muse, mutect2, varscan2
- KCNH5 | c.1307G>A p.G436E | Missense Mutation (SNP) | VAF 87/202 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59753801; called by muse, mutect2, varscan2
- KCNH7 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59811411; called by muse, mutect2, varscan2
- KCNJ12 | c.1121C>A p.S374Y | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV59166180; called by muse, mutect2, varscan2
- KCNK10 | c.1077C>A p.S359R | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100069111, COSV56641030; called by muse, mutect2, varscan2
- KDM5C | c.1616C>T p.S539L | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100948908; called by muse, mutect2, varscan2
- KDM6A | c.2077G>T p.G693W | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1044524871; called by muse, mutect2, varscan2
- KEAP1 | c.556G>C p.G186R | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50260458, COSV50275012, COSV50315065; called by muse, mutect2, varscan2
- KHDC3L | c.443C>A p.S148* | Nonsense Mutation (SNP) | VAF 8/53 reads (15%) | catalogued as COSV64863056; called by muse, mutect2, varscan2
- KIF27 | c.191G>C p.C64S | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT tolerated (0.12); PolyPhen benign (0.27); catalogued as COSV99926686; called by muse, mutect2, varscan2
- KIR2DL1 | c.665-1G>T p.X222_splice | Splice Site (SNP) | VAF 127/924 reads (14%) | catalogued as COSV99382684; called by muse, mutect2, varscan2
- KLHL1 | c.1346C>G p.P449R | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as rs753185463, COSV64775572, COSV64787031; called by muse, mutect2, varscan2
- KLHL4 | c.305C>A p.A102E | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.157); catalogued as COSV64148468; called by muse, mutect2, varscan2
- KLHL7 | c.1639G>A p.E547K (on ENST00000339077 / NM_001031710.3; = p.E499K on NM_018846.5) | Missense Mutation (SNP) | VAF 96/183 reads (52%) | SIFT tolerated (1); PolyPhen probably damaging (0.958); catalogued as rs370732317; called by muse, mutect2, varscan2
- KMT2D | c.5224G>T p.E1742* | Nonsense Mutation (SNP) | VAF 187/294 reads (64%) | catalogued as COSV56481520; called by muse, mutect2, varscan2
- KMT2D | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 105/152 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1323918085; called by muse, mutect2, varscan2
- KRT20 | c.1114C>A p.R372S | Missense Mutation (SNP) | VAF 301/815 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.625); catalogued as COSV51425044; called by muse, mutect2, varscan2
- KRTAP19-4 | c.188T>C p.L63P | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.176); catalogued as rs1235839260; called by muse, mutect2, varscan2
- LHCGR | c.1939_1940insA p.R647Qfs*3 | Frame Shift Ins (INS) | VAF 111/392 reads (28%) | catalogued as COSV99683210; called by mutect2, pindel, varscan2
- LMO7 | c.4916C>A p.S1639Y (on ENST00000357063; = p.S1320Y on NM_005358.5) | Missense Mutation (SNP) | VAF 82/401 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as COSV58530329; called by muse, mutect2, varscan2
- LNPEP | c.2173G>T p.D725Y | Missense Mutation (SNP) | VAF 259/587 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.149); catalogued as COSV51479659; called by muse, mutect2, varscan2
- LRIT1 | c.821G>T p.R274L | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372728854; called by muse, mutect2, varscan2
- LRP12 | c.2428T>C p.Y810H | Missense Mutation (SNP) | VAF 135/326 reads (41%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV52627635; called by muse, mutect2, varscan2
- LRP1B | c.11178C>G p.N3726K | Missense Mutation (SNP) | VAF 52/318 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV101261602; called by muse, mutect2, varscan2
- LRP1B | c.4436G>A p.G1479E | Missense Mutation (SNP) | VAF 114/292 reads (39%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); catalogued as rs1224225080; called by muse, mutect2, varscan2
- LRP1B | c.2765G>T p.C922F | Missense Mutation (SNP) | VAF 77/211 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63341637; called by muse, mutect2, varscan2
- LRRC8A | c.2054G>A p.R685H | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.931); catalogued as rs1356244793; called by muse, mutect2, varscan2
- LVRN | c.2835G>A p.L945= | Splice Region (SNP) | VAF 83/173 reads (48%) | catalogued as rs750399390; called by muse, mutect2, varscan2
- MAEL | c.481G>C p.G161R | Missense Mutation (SNP) | VAF 96/274 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV99057621; called by muse, mutect2, varscan2
- MAGEC3 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.061); catalogued as rs370315828, COSV74217389; called by muse, mutect2, varscan2
- MAP4K1 | c.1621C>T p.R541W | Missense Mutation (SNP) | VAF 216/406 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs770505238; called by muse, mutect2, varscan2
- MATN2 | c.464G>T p.R155L | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765751317; called by muse, mutect2, varscan2
- MATN4 | c.127C>A p.R43S | Missense Mutation (SNP) | VAF 37/123 reads (30%) | PolyPhen probably damaging (0.998); catalogued as COSV100637084, COSV100637122; called by muse, mutect2, varscan2
- MBD5 | c.3588G>T p.Q1196H | Missense Mutation (SNP) | VAF 66/205 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); catalogued as COSV68695834; called by muse, mutect2, varscan2
- MMP17 | c.1322A>G p.D441G | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as rs1321584847; called by muse, mutect2, varscan2
- MON1B | c.1331A>T p.E444V | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50247386; called by muse, mutect2, varscan2
- MUC16 | c.26399G>T p.G8800V | Missense Mutation (SNP) | VAF 91/267 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.399); catalogued as rs758795123, COSV67492955; called by muse, mutect2, varscan2
- MUC16 | c.26398G>A p.G8800S | Missense Mutation (SNP) | VAF 89/264 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.556); catalogued as rs769472638, COSV101200624; called by muse, mutect2, varscan2
- MYCN | c.1193G>T p.R398L | Missense Mutation (SNP) | VAF 104/401 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55260389, COSV55261356; called by muse, mutect2, varscan2
- N4BP2L2 | c.2107A>G p.T703A (on ENST00000674422; = p.T274A on NM_033111.4) | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.171); catalogued as rs1462904647; called by muse, mutect2, varscan2
- NBEA | c.6773G>T p.G2258V | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV59759569, COSV99060790; called by muse, mutect2, varscan2
- NCAM2 | c.595del p.R199Vfs*30 | Frame Shift Del (DEL) | VAF 43/133 reads (32%) | catalogued as COSV53070591; called by mutect2, pindel, varscan2
- NCAPG2 | c.1891A>G p.K631E | Missense Mutation (SNP) | VAF 84/184 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1339546833; called by muse, mutect2, varscan2
- NCKAP1 | c.907A>T p.I303F | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.964); catalogued as rs200960008; called by muse, mutect2, varscan2
- NDST4 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 102/207 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as rs755372289, COSV52142690; called by muse, mutect2, varscan2
- NDUFS1 | c.2093-1G>T p.X698_splice | Splice Site (SNP) | VAF 36/98 reads (37%) | catalogued as COSV99260429; called by muse, mutect2, varscan2
- NHS | c.2938C>A p.P980T | Missense Mutation (SNP) | VAF 57/114 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66271473; called by muse, mutect2, varscan2
- NID1 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as rs750625934, COSV51615363; called by muse, mutect2, varscan2
- NOX4 | c.1443C>A p.N481K | Missense Mutation (SNP) | VAF 41/204 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs763548956; called by muse, mutect2, varscan2
- NPAP1 | c.2288C>G p.P763R | Missense Mutation (SNP) | VAF 75/150 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV61512227; called by muse, mutect2, varscan2
- NRDC | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100704002; called by muse, varscan2
- NSUN6 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1339746650; called by muse, mutect2, varscan2
- NT5E | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 208/523 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs200840390; called by muse, mutect2, varscan2
- NUP205 | c.5902A>G p.I1968V | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs368180701; called by muse, mutect2, varscan2
- NUP210L | c.5350G>A p.V1784M | Missense Mutation (SNP) | VAF 189/923 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs1450498063; called by muse, mutect2, varscan2
- NXF3 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 90/133 reads (68%) | SIFT tolerated (0.17); PolyPhen benign (0.192); catalogued as COSV101221906; called by muse, mutect2, varscan2
- OLFML2B | c.2162C>G p.T721R | Missense Mutation (SNP) | VAF 208/468 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54200065; called by muse, mutect2, varscan2
- OMP | c.104G>T p.R35L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.009); catalogued as COSV99582284; called by muse, mutect2, varscan2
- OPCML | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762120321, COSV59404700; called by muse, mutect2, varscan2
- OR11H1 | c.728C>A p.S243Y | Missense Mutation (SNP) | VAF 253/665 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99421594, COSV99421966; called by muse, mutect2, varscan2
- OR1M1 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 54/232 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754863155, COSV70036813; called by muse, mutect2, varscan2
- OR2L13 | c.569A>G p.D190G | Missense Mutation (SNP) | VAF 127/407 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as rs1208138847, COSV63564022; called by muse, mutect2, varscan2
- OR2L8 | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 183/509 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.483); catalogued as COSV100594040; called by muse, mutect2, varscan2
- OR4A15 | c.547T>A p.L183M | Missense Mutation (SNP) | VAF 158/356 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59035522; called by muse, mutect2, varscan2
- OR4K2 | c.130C>G p.L44V | Missense Mutation (SNP) | VAF 224/686 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.399); catalogued as rs772191565, COSV100064150; called by muse, mutect2, varscan2
- OR51B5 | c.395C>A p.S132Y | Missense Mutation (SNP) | VAF 66/145 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV56176544; called by muse, mutect2, varscan2
- OR5AC2 | c.790C>G p.P264A | Missense Mutation (SNP) | VAF 56/214 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV62279541; called by muse, mutect2, varscan2
- OR5M3 | c.604G>A p.G202S | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as rs201997492, COSV56567819; called by muse, mutect2, varscan2
- OR9A4 | c.542G>C p.R181P | Missense Mutation (SNP) | VAF 239/702 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.745); catalogued as rs782482254, COSV71885099; called by muse, mutect2, varscan2
- PCDH11X | c.1811C>T p.A604V | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.6); PolyPhen benign (0.196); catalogued as COSV100008496; called by mutect2, varscan2
- PCDH11X | c.3611C>T p.T1204I | Missense Mutation (SNP) | VAF 98/155 reads (63%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV100008505; called by muse, mutect2, varscan2
- PCDH18 | c.3364G>T p.V1122L | Missense Mutation (SNP) | VAF 97/146 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100787326; called by muse, mutect2, varscan2
- PCDHB5 | c.2155G>T p.A719S | Missense Mutation (SNP) | VAF 94/179 reads (53%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.056); catalogued as COSV50654544, COSV99167656; called by muse, mutect2, varscan2
- PCDHGB4 | c.1339G>C p.A447P | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.041); catalogued as COSV53989324; called by muse, mutect2, varscan2
- PCDHGB6 | c.1552C>T p.R518C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.791); catalogued as rs759945612; called by muse, mutect2, varscan2
- PDE10A | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 82/232 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs370604056; called by muse, mutect2, varscan2
- PDILT | c.640C>A p.R214S | Missense Mutation (SNP) | VAF 184/575 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.289); catalogued as rs144890989, COSV56699975; called by muse, mutect2, varscan2
- PIK3R6 | c.1903C>A p.L635M | Missense Mutation (SNP) | VAF 44/69 reads (64%) | SIFT tolerated (0.24); PolyPhen benign (0.357); catalogued as COSV61004280; called by muse, mutect2, varscan2
- PKHD1L1 | c.4216G>A p.G1406S | Missense Mutation (SNP) | VAF 124/207 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780000649; called by muse, mutect2, varscan2
- PLCB1 | c.1617A>T p.E539D | Missense Mutation (SNP) | VAF 60/182 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV62037575; called by muse, mutect2, varscan2
- PLEC | c.12887G>C p.R4296P (on ENST00000322810 / NM_201380.4; = p.R4186P on NM_000445.5) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV59647172; called by muse, mutect2
- PMEPA1 | c.624dup p.S209Qfs*3 | Frame Shift Ins (INS) | VAF 9/59 reads (15%) | catalogued as rs751873496; called by mutect2, varscan2
- POTEE | c.2080C>G p.L694V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs571742663; called by muse, mutect2, varscan2
- PTPN22 | c.803A>G p.Q268R | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63084630; called by muse, mutect2, varscan2
- PTPRN | c.895C>A p.Q299K | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV55346726; called by muse, mutect2, varscan2
- PXDNL | c.3372G>T p.Q1124H | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV100687027; called by muse, mutect2, varscan2
- RELN | c.3591C>A p.F1197L | Missense Mutation (SNP) | VAF 217/615 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV59003987; called by muse, mutect2, varscan2
- RNF217 | c.1281+1G>T p.X427_splice (on ENST00000521654 / NM_001286398.2; = p.X135_splice on NM_152553.5) | Splice Site (SNP) | VAF 23/116 reads (20%) | catalogued as COSV99254834; called by muse, mutect2, varscan2
- SEC11A | c.223G>C p.D75H | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.897); catalogued as COSV99190171; called by muse, mutect2, varscan2
- SEC14L3 | c.492G>T p.W164C | Missense Mutation (SNP) | VAF 48/205 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs570127053; called by muse, mutect2, varscan2
- SELE | c.631G>T p.D211Y | Missense Mutation (SNP) | VAF 138/269 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV60973772; called by muse, mutect2, varscan2
- SEPTIN2 | c.1045G>T p.G349C | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.29); catalogued as COSV63633519; called by muse, mutect2, varscan2
- SERPINB12 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 423/572 reads (74%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771057082; called by muse, mutect2, varscan2
- SERPINB3 | c.883C>G p.L295V | Missense Mutation (SNP) | VAF 83/669 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52192006, COSV52193818; called by muse, mutect2, varscan2
- SGCD | c.519C>A p.F173L (on ENST00000435422 / NM_001128209.2; = p.F174L on NM_000337.5) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV61918514; called by muse, mutect2, varscan2
- SGIP1 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.162); catalogued as COSV52764607; called by muse, mutect2, varscan2
- SI | c.4267+1G>A p.X1423_splice | Splice Site (SNP) | VAF 79/227 reads (35%) | catalogued as rs199897248, COSV100014159; called by muse, mutect2, varscan2
- SLC5A1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 23/80 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV99833217; called by muse, mutect2, varscan2
- SLITRK2 | c.1887C>A p.F629L | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV59422958; called by muse, mutect2, varscan2
- SMG1 | c.551T>C p.V184A | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs761215949, COSV101245240; called by muse, mutect2, varscan2
- SMURF2 | c.614T>C p.F205S | Missense Mutation (SNP) | VAF 119/289 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.075); catalogued as COSV99300219; called by muse, mutect2, varscan2
- SPTBN4 | c.1514G>T p.R505L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV58955117; called by muse, mutect2, varscan2
- STK36 | c.2180G>T p.G727V | Missense Mutation (SNP) | VAF 54/392 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV55329085; called by muse, varscan2
- SYT1 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 28/92 reads (30%) | catalogued as COSV54049842; called by muse, mutect2, varscan2
- TAAR1 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 91/707 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV99257483; called by muse, mutect2, varscan2
- TACR3 | c.900G>T p.M300I | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs777530972, COSV59199110, COSV59201153; called by muse, mutect2, varscan2
- TAL2 | c.175G>A p.G59R | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs775375184; called by muse, varscan2
- TBC1D17 | c.927+1G>T p.X309_splice | Splice Site (SNP) | VAF 12/26 reads (46%) | catalogued as rs200802990, COSV99680418; called by muse, mutect2, varscan2
- TDGF1 | c.402G>A p.W134* | Nonsense Mutation (SNP) | VAF 72/145 reads (50%) | catalogued as rs756132962; called by muse, mutect2, varscan2
- TEX43 | c.71A>G p.Y24C | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs770108067; called by muse, mutect2, varscan2
- TGM6 | c.1386C>A p.F462L | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV52479748; called by muse, mutect2, varscan2
- TMEM200A | c.313A>G p.I105V | Missense Mutation (SNP) | VAF 71/349 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs774068784; called by muse, mutect2, varscan2
- TNN | c.3062G>T p.R1021L | Missense Mutation (SNP) | VAF 84/382 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.36); catalogued as COSV53434768; called by muse, mutect2, varscan2
- TRAV8-3 | c.161G>A p.W54* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as rs1457909560; called by muse, mutect2, varscan2
- TRIM29 | c.58C>G p.R20G | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV100531666; called by muse, mutect2, varscan2
- TRIM58 | c.652A>T p.S218C | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as COSV63569906; called by muse, mutect2, varscan2
- TRIM58 | c.1073G>T p.W358L | Missense Mutation (SNP) | VAF 104/360 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63569515, COSV63571737; called by muse, mutect2, varscan2
- TRIM58 | c.1074G>T p.W358C | Missense Mutation (SNP) | VAF 104/357 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100825193; called by muse, mutect2, varscan2
- TRPA1 | c.2978G>T p.W993L | Missense Mutation (SNP) | VAF 39/289 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as COSV51563874, COSV51569055; called by muse, mutect2, varscan2
- TRPC7 | c.240C>G p.N80K | Missense Mutation (SNP) | VAF 71/252 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs372900766, COSV61456123; called by muse, mutect2, varscan2
- TRUB2 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs540243770; called by muse, mutect2, varscan2
- TTN | c.102310T>A p.S34104T (on ENST00000591111; = p.S26680T on NM_003319.4) | Missense Mutation (SNP) | VAF 20/73 reads (27%) | PolyPhen benign (0.068); catalogued as COSV60196412; called by muse, mutect2, varscan2
- TTN | c.97852G>C p.E32618Q (on ENST00000591111; = p.E25194Q on NM_003319.4) | Missense Mutation (SNP) | VAF 50/131 reads (38%) | PolyPhen possibly damaging (0.856); catalogued as COSV60223081; called by muse, mutect2, varscan2
- TTN | c.85180C>A p.R28394S (on ENST00000591111; = p.R20970S on NM_003319.4) | Missense Mutation (SNP) | VAF 76/191 reads (40%) | PolyPhen benign (0.372); catalogued as COSV60002845; called by muse, mutect2, varscan2
- TTN | c.79651G>C p.E26551Q (on ENST00000591111; = p.E19127Q on NM_003319.4) | Missense Mutation (SNP) | VAF 32/76 reads (42%) | PolyPhen probably damaging (0.997); catalogued as COSV60047934; called by muse, mutect2, varscan2
- TTN | c.79359G>C p.K26453N (on ENST00000591111; = p.K19029N on NM_003319.4) | Missense Mutation (SNP) | VAF 65/128 reads (51%) | PolyPhen probably damaging (0.997); catalogued as COSV60069665; called by muse, mutect2, varscan2
- UBE2D3 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as COSV57660365; called by muse, mutect2, varscan2
- UPK1B | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 54/202 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs755357574, COSV51767219; called by muse, mutect2, varscan2
- XIRP2 | c.5302G>T p.G1768C (on ENST00000628543; = p.G1943C on NM_152381.6) | Missense Mutation (SNP) | VAF 72/220 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.436); catalogued as COSV54714082; called by muse, mutect2, varscan2
- YIPF4 | c.337C>G p.P113A | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs780167554; called by muse, mutect2, varscan2
- ZDHHC21 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 18/191 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.229); catalogued as rs1381034998; called by muse, mutect2
- ZFC3H1 | c.2705G>T p.R902L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66432073; called by muse, mutect2, varscan2
- ZFPM2 | c.80G>A p.C27Y | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1437224917; called by muse, mutect2, varscan2
- ZNF138 | c.328G>T p.G110C (on ENST00000307355 / NM_001367572.1; = p.G84C on NM_006524.4) | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.882); catalogued as COSV56464604; called by muse, mutect2, varscan2
- ZNF154 | c.986A>G p.Y329C | Missense Mutation (SNP) | VAF 189/378 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs752065572; called by muse, mutect2, varscan2
- ZNF347 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 76/264 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1198751239; called by muse, mutect2, varscan2
- ZNF426 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 83/242 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV53469129; called by muse, mutect2, varscan2
- ZNF528 | c.1802G>A p.G601E | Missense Mutation (SNP) | VAF 127/267 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100846657, COSV64621183; called by muse, varscan2
- ZNF573 | c.1354A>G p.T452A (on ENST00000536220 / NM_001172692.1; = p.T394A on NM_152360.3) | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.281); catalogued as rs758426457; called by muse, mutect2, varscan2
- ZNF574 | c.2308G>C p.D770H | Missense Mutation (SNP) | VAF 160/912 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55905712, COSV55906893, COSV55907568; called by muse, mutect2, varscan2
- ZNF98 | c.405C>A p.H135Q | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV100757308; called by muse, mutect2, varscan2
- A1CF | c.970C>A p.Q324K | Missense Mutation (SNP) | VAF 66/162 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ADAMTS19 | c.1858T>A p.C620S | Missense Mutation (SNP) | VAF 125/385 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS19 | c.3298G>T p.G1100C | Missense Mutation (SNP) | VAF 88/284 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAMTS20 | c.4499G>A p.C1500Y | Missense Mutation (SNP) | VAF 83/265 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAMTS5 | c.2301C>A p.D767E | Missense Mutation (SNP) | VAF 11/282 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- ADAMTS5 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 97/256 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRE3 | c.1714G>T p.V572L | Missense Mutation (SNP) | VAF 73/236 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- ADGRL1 | c.752C>A p.T251N (on ENST00000340736 / NM_001008701.3; = p.T246N on NM_014921.5) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRL2 | c.3506G>T p.G1169V | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ADSS2 | c.690G>T p.M230I | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- AFF3 | c.2593G>T p.V865L | Missense Mutation (SNP) | VAF 30/211 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKT2 | c.360G>T p.M120I | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ALDH8A1 | c.1400G>C p.R467T | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK2 | c.2575G>A p.G859R | Missense Mutation (SNP) | VAF 37/385 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2
- ANKAR | c.700G>C p.A234P | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2428G>A p.E810K | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ANKRD33 | c.233G>T p.C78F (on ENST00000340970 / NM_001304459.2; = p.X213_splice on NM_182608.4) | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- ANKS1B | c.2072C>G p.S691* | Nonsense Mutation (SNP) | VAF 71/187 reads (38%) | called by muse, mutect2, varscan2
- AQP12A | c.98C>G p.A33G | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ARG1 | c.600G>A p.M200I | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.879); called by muse, mutect2
- ARHGAP32 | c.371A>G p.H124R | Missense Mutation (SNP) | VAF 79/134 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ARHGEF28 | c.3889A>G p.S1297G | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT tolerated (0.35); PolyPhen benign (0.071); called by muse, varscan2
- ARMC4 | c.423T>A p.Y141* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | called by muse, varscan2
- ARPP21 | c.1202G>T p.S401I | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ASH1L | c.1858C>G p.H620D | Missense Mutation (SNP) | VAF 78/376 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ATF7IP | c.2136del p.Q714Kfs*4 | Frame Shift Del (DEL) | VAF 31/109 reads (28%) | called by mutect2, pindel, varscan2
- ATG10 | c.104C>G p.S35* | Nonsense Mutation (SNP) | VAF 52/100 reads (52%) | called by muse, varscan2
- ATG4C | c.87G>T p.L29F | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.248); called by muse, mutect2
- ATP12A | c.365del p.G122Afs*21 | Frame Shift Del (DEL) | VAF 284/1422 reads (20%) | called by pindel, varscan2
- ATP2A1 | c.2353G>C p.E785Q | Missense Mutation (SNP) | VAF 67/208 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- AVPR1B | c.1194T>A p.S398R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- BBS10 | c.201G>A p.M67I | Missense Mutation (SNP) | VAF 325/528 reads (62%) | SIFT tolerated (0.25); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- BFSP2 | c.548C>A p.A183D | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- C12orf50 | c.253A>T p.N85Y | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- CA12 | c.452C>G p.S151* | Nonsense Mutation (SNP) | VAF 63/102 reads (62%) | called by muse, mutect2, varscan2
- CA4 | c.633G>C p.E211D | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- CA6 | c.230A>G p.E77G | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- CACNB2 | c.1399C>A p.P467T (on ENST00000324631 / NM_201596.3; = p.P412T on NM_000724.4) | Missense Mutation (SNP) | VAF 175/492 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNG3 | c.293T>A p.L98Q | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CAMSAP2 | c.4190A>G p.N1397S (on ENST00000236925 / NM_001297707.2; = p.N1386S on NM_203459.3) | Missense Mutation (SNP) | VAF 70/162 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CASS4 | c.791C>G p.A264G | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC110 | c.2140G>C p.D714H | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CCL5 | c.234G>C p.K78N | Missense Mutation (SNP) | VAF 167/564 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CCR10 | c.94T>A p.Y32N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0.007); called by mutect2, varscan2
- CCSER1 | c.871G>C p.D291H | Missense Mutation (SNP) | VAF 206/541 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- CD22 | c.617T>G p.F206C | Missense Mutation (SNP) | VAF 96/195 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CD5L | c.605G>T p.W202L | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- CDC27 | c.2128G>A p.A710T | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDR1 | c.163G>T p.V55L | Missense Mutation (SNP) | VAF 63/104 reads (61%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEACAM3 | c.74T>C p.L25P | Missense Mutation (SNP) | VAF 279/580 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- CEACAM5 | c.1180G>A p.G394R | Missense Mutation (SNP) | VAF 51/582 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- CENPE | c.6477C>A p.N2159K | Missense Mutation (SNP) | VAF 19/253 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.24); called by muse, mutect2
- CEP350 | c.1428G>T p.R476S | Missense Mutation (SNP) | VAF 173/462 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- CHRD | c.647C>A p.S216Y | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- CHRM3 | c.997A>G p.S333G | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- CHUK | c.937G>T p.V313L | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.27); PolyPhen benign (0.048); called by mutect2, varscan2
- CNTN5 | c.3183G>T p.R1061S | Missense Mutation (SNP) | VAF 31/259 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- COL5A3 | c.1390G>T p.A464S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CPA3 | c.901A>G p.I301V | Missense Mutation (SNP) | VAF 184/403 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CSMD1 | c.7596G>T p.Q2532H (on ENST00000520002; = p.Q2531H on NM_033225.6) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CSMD3 | c.7222A>T p.T2408S (on ENST00000297405 / NM_001363185.1; = p.T2304S on NM_052900.3) | Missense Mutation (SNP) | VAF 53/328 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- CSMD3 | c.2960C>A p.T987K (on ENST00000297405 / NM_001363185.1; = p.T883K on NM_052900.3) | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSN3 | c.256G>T p.V86L | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.42); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CSPP1 | c.3652A>G p.T1218A (on ENST00000676605; = p.T1177A on NM_024790.6) | Missense Mutation (SNP) | VAF 90/1158 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); called by muse, mutect2
- CSRNP3 | c.1549A>C p.S517R | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CTRB2 | c.740C>A p.A247D | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CUBN | c.2167G>T p.E723* | Nonsense Mutation (SNP) | VAF 28/110 reads (25%) | called by muse, mutect2, varscan2
- CUL3 | c.596C>A p.S199* | Nonsense Mutation (SNP) | VAF 19/66 reads (29%) | called by muse, mutect2, varscan2
- CUL9 | c.6768A>T p.K2256N | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- CYTIP | c.252T>A p.D84E | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- DDB1 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 83/202 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DGKH | c.438G>T p.M146I | Missense Mutation (SNP) | VAF 124/556 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- DGKH | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 121/548 reads (22%) | called by muse, mutect2, varscan2
- DHX37 | c.3309G>T p.E1103D | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2
- DLEC1 | c.1774G>T p.A592S | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- DLGAP2 | c.1260del p.T421Pfs*13 | Frame Shift Del (DEL) | VAF 34/55 reads (62%) | called by mutect2, pindel, varscan2
- DLL4 | c.164G>C p.R55P | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH7 | c.817G>T p.A273S | Missense Mutation (SNP) | VAF 51/272 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DPY19L1 | c.1609G>C p.E537Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.926); called by muse, mutect2
- DSC2 | c.2063G>T p.G688V | Missense Mutation (SNP) | VAF 54/296 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DST | c.15646G>A p.A5216T (on ENST00000361203 / NM_001374722.1; = p.A2804T on NM_015548.5) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.039); called by mutect2, varscan2
- DYNC2H1 | c.6934C>G p.Q2312E | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by muse, mutect2
- DZIP3 | c.2075A>G p.Q692R | Missense Mutation (SNP) | VAF 77/302 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DZIP3 | c.2601A>T p.L867F | Missense Mutation (SNP) | VAF 100/560 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EFHD1 | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ESYT2 | c.1290C>G p.I430M (on ENST00000613624; = p.I354M on NM_020728.3) | Missense Mutation (SNP) | VAF 208/390 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- EXOC2 | c.2436G>T p.E812D | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- EYS | c.634C>A p.Q212K | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- F11 | c.1139G>T p.C380F | Missense Mutation (SNP) | VAF 89/199 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM47C | c.2828T>A p.L943H | Missense Mutation (SNP) | VAF 104/152 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FAM71B | c.1532C>T p.T511I | Missense Mutation (SNP) | VAF 61/224 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- FAP | c.283A>G p.M95V | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- FBN2 | c.6416C>A p.P2139H | Missense Mutation (SNP) | VAF 74/262 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by mutect2, varscan2
- FCRL5 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 131/332 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- FGB | c.184G>C p.A62P | Missense Mutation (SNP) | VAF 41/67 reads (61%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- FGF23 | c.731G>T p.C244F | Missense Mutation (SNP) | VAF 65/161 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- FGFR4 | c.2212C>A p.Q738K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- FLRT2 | c.1460C>A p.S487Y | Missense Mutation (SNP) | VAF 72/129 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FOLR3 | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- FOXN1 | c.1848del p.Y617Tfs*59 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- FSCB | c.2438T>G p.V813G | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); called by muse, mutect2
- GAS2L2 | c.1084A>T p.R362W | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GEMIN5 | c.2533G>T p.A845S | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GGNBP2 | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GIGYF2 | c.2193G>T p.K731N | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GIN1 | c.405G>T p.K135N | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- GOLGB1 | c.3008A>G p.K1003R | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GOLIM4 | c.1030G>T p.E344* | Nonsense Mutation (SNP) | VAF 56/231 reads (24%) | called by muse, mutect2, varscan2
- GPR179 | c.3424C>T p.Q1142* (on ENST00000621958; = p.Q1141* on NM_001004334.4) | Nonsense Mutation (SNP) | VAF 52/158 reads (33%) | called by muse, varscan2
- GPRIN3 | c.1340G>A p.R447K | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.114); called by muse, mutect2
- GRK5 | c.805G>T p.G269C | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GTDC1 | c.88G>T p.V30F | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- HAUS8 | c.929+1G>A p.X310_splice | Splice Site (SNP) | VAF 44/310 reads (14%) | called by muse, varscan2
- HECTD4 | c.1544G>T p.G515V | Missense Mutation (SNP) | VAF 117/336 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HNRNPF | c.622G>C p.G208R | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- HOXD9 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- HSD17B4 | c.1181C>T p.S394F (on ENST00000414835 / NM_001199291.3; = p.S369F on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 77/175 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- HTR3B | c.878C>A p.P293Q | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ICE1 | c.4885G>A p.G1629R | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ICOS | c.349C>G p.P117A | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IFT172 | c.1938G>A p.R646= | Splice Region (SNP) | VAF 40/113 reads (35%) | called by muse, mutect2, varscan2
- IGKV2D-24 | c.145C>A p.L49I | Missense Mutation (SNP) | VAF 145/419 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- IL12B | c.899G>T p.C300F | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- IL4R | c.2299G>A p.G767S | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ILKAP | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- INTS8 | c.1258G>C p.E420Q | Missense Mutation (SNP) | VAF 82/171 reads (48%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- IPCEF1 | c.82A>T p.T28S | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IPO8 | c.162G>C p.Q54H | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IRAK1 | c.1126A>C p.S376R | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.479); called by mutect2, varscan2
- IWS1 | c.451G>A p.V151I | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- KALRN | c.7991A>T p.E2664V (on ENST00000360013 / NM_001024660.4; = p.E967V on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 123/454 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.363); called by muse, mutect2
- KATNIP | c.4000G>C p.D1334H | Missense Mutation (SNP) | VAF 111/318 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KBTBD8 | c.604A>C p.S202R | Missense Mutation (SNP) | VAF 61/128 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- KCMF1 | c.355G>T p.G119C | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNJ4 | c.1273C>A p.L425M | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.577); called by mutect2, varscan2
- KCNN1 | c.326A>C p.Y109S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KCNU1 | c.613G>C p.E205Q | Missense Mutation (SNP) | VAF 59/375 reads (16%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- KCTD19 | c.1883C>A p.P628H | Missense Mutation (SNP) | VAF 70/136 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- KDM8 | c.459G>T p.R153S | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- KIAA1755 | c.2251C>A p.P751T | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.32); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- KIF13B | c.1221G>C p.M407I | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- KIR3DL2 | c.1119G>T p.M373I | Missense Mutation (SNP) | VAF 129/612 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- KLK15 | c.573del p.M192Wfs*62 | Frame Shift Del (DEL) | VAF 43/105 reads (41%) | called by mutect2, pindel, varscan2
- KNG1 | c.1773C>G p.I591M | Missense Mutation (SNP) | VAF 98/467 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- KRT77 | c.1257G>T p.Q419H | Missense Mutation (SNP) | VAF 78/212 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- KRT83 | c.1138C>A p.L380M | Missense Mutation (SNP) | VAF 115/350 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAS1L | c.971A>T p.D324V | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRIT1 | c.1399G>C p.G467R | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP1B | c.8570G>T p.C2857F | Missense Mutation (SNP) | VAF 59/214 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LVRN | c.1257C>G p.H419Q | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEC3 | c.1438del p.A480Qfs*4 | Frame Shift Del (DEL) | VAF 41/109 reads (38%) | called by mutect2, pindel, varscan2
- MAML1 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 99/329 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- MAP2 | c.2108A>G p.N703S | Missense Mutation (SNP) | VAF 180/470 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MARCHF10 | c.694C>G p.H232D | Missense Mutation (SNP) | VAF 130/339 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- MB21D2 | c.1399G>T p.G467* | Nonsense Mutation (SNP) | VAF 100/383 reads (26%) | called by muse, mutect2, varscan2
- MBOAT1 | c.976G>T p.D326Y | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- MDN1 | c.1038_1056del p.G347Sfs*36 | Frame Shift Del (DEL) | VAF 150/393 reads (38%) | called by mutect2, varscan2
- MKNK1 | c.1337A>G p.D446G | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMP16 | c.1576C>T p.L526F | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, varscan2
- MMP17 | c.1321G>T p.D441Y | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- MMP9 | c.737C>A p.T246N | Missense Mutation (SNP) | VAF 69/229 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- MOCOS | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 59/131 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- MOGAT3 | c.604C>A p.P202T | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- MRC2 | c.3103dup p.W1035Lfs*33 | Frame Shift Ins (INS) | VAF 38/180 reads (21%) | called by mutect2, pindel, varscan2
- MRGPRX1 | c.561A>T p.L187F | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- MRPL51 | c.188T>A p.L63Q | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MS4A4A | c.461G>A p.S154N | Missense Mutation (SNP) | VAF 63/139 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- MTM1 | c.601C>G p.L201V | Missense Mutation (SNP) | VAF 109/196 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MTR | c.1795C>T p.L599F | Missense Mutation (SNP) | VAF 75/230 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MTREX | c.1861G>C p.E621Q | Missense Mutation (SNP) | VAF 40/60 reads (67%) | SIFT tolerated (0.23); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- MUC16 | c.42515G>A p.G14172D | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC16 | c.29535C>G p.I9845M | Missense Mutation (SNP) | VAF 71/465 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- MUC17 | c.12568C>G p.L4190V | Missense Mutation (SNP) | VAF 114/213 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- MXRA5 | c.7087G>T p.V2363L | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- MYG1 | c.392G>T p.S131I | Missense Mutation (SNP) | VAF 205/494 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MYH13 | c.4120C>A p.Q1374K | Missense Mutation (SNP) | VAF 171/316 reads (54%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.911); called by muse, varscan2
- MYH13 | c.4033G>T p.D1345Y | Missense Mutation (SNP) | VAF 97/180 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- MYH15 | c.1394G>T p.R465M | Missense Mutation (SNP) | VAF 90/193 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MYH4 | c.785C>A p.A262D | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYH6 | c.1567G>T p.D523Y | Missense Mutation (SNP) | VAF 42/64 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- MYO16 | c.3349C>G p.Q1117E | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- MYO7A | c.2905G>A p.D969N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); called by muse, mutect2
- MYO7B | c.1388A>T p.Q463L | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MYOM2 | c.4372G>T p.A1458S | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- NAV3 | c.5590C>G p.R1864G (on ENST00000397909 / NM_001024383.2; = p.R1842G on NM_014903.6) | Missense Mutation (SNP) | VAF 82/195 reads (42%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NBAS | c.3997A>T p.T1333S | Missense Mutation (SNP) | VAF 332/955 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- NBEAL1 | c.7222C>T p.H2408Y | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NCOA7 | c.652G>T p.V218L | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- NDST3 | c.2385C>A p.Y795* | Nonsense Mutation (SNP) | VAF 55/94 reads (59%) | called by muse, mutect2, varscan2
- NECTIN3 | c.1351A>G p.K451E | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- NEUROD1 | c.594G>T p.E198D | Missense Mutation (SNP) | VAF 361/525 reads (69%) | SIFT tolerated (0.14); PolyPhen benign (0.173); called by muse, varscan2
- NEUROD6 | c.514C>A p.P172T | Missense Mutation (SNP) | VAF 187/321 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NEXMIF | c.244G>T p.G82C | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NHS | c.2504C>T p.S835L | Missense Mutation (SNP) | VAF 198/510 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NINL | c.2424G>C p.E808D | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NKX2-5 | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.905); called by muse, varscan2
- NPFFR1 | c.116C>G p.T39S | Missense Mutation (SNP) | VAF 77/190 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NR1H2 | c.586G>A p.G196R | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- NTSR2 | c.1073A>T p.Y358F | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- NUDT6 | c.486A>T p.Q162H | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- OAS3 | c.701T>C p.I234T | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- OLFM4 | c.227C>A p.S76Y | Missense Mutation (SNP) | VAF 85/354 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- OR10AD1 | c.631C>G p.P211A | Missense Mutation (SNP) | VAF 131/483 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- OR13A1 | c.878G>T p.G293V | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- OR13D1 | c.481C>A p.P161T | Missense Mutation (SNP) | VAF 123/211 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR14A16 | c.62T>G p.M21R | Missense Mutation (SNP) | VAF 73/214 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR2G6 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 78/253 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- OR4C12 | c.489G>T p.W163C | Missense Mutation (SNP) | VAF 216/671 reads (32%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- OR4F15 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 178/346 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by mutect2, varscan2
- OR4K14 | c.107T>A p.V36E | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- OR4K2 | c.236del p.P79Qfs*3 | Frame Shift Del (DEL) | VAF 96/572 reads (17%) | called by pindel, varscan2*
- OR5D13 | c.232G>T p.V78L | Missense Mutation (SNP) | VAF 129/310 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- OR8H2 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 257/654 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OSBPL8 | c.562G>C p.V188L | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- OTUD7B | c.308G>C p.S103T | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- OXCT1 | c.951G>C p.M317I | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PAN3 | c.2391G>C p.Q797H | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PAPPA2 | c.1052C>G p.T351S | Missense Mutation (SNP) | VAF 67/307 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- PAPPA2 | c.2900C>A p.T967N | Missense Mutation (SNP) | VAF 437/1056 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- PCDHA2 | c.1196C>G p.S399C | Missense Mutation (SNP) | VAF 62/243 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHA4 | c.2171C>A p.S724Y | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- PCDHA9 | c.1586A>T p.E529V | Missense Mutation (SNP) | VAF 75/127 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- PCDHB6 | c.1064C>A p.P355Q | Missense Mutation (SNP) | VAF 75/195 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PCDHGA6 | c.2126T>G p.I709S | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- PCGF5 | c.297G>C p.K99N | Missense Mutation (SNP) | VAF 140/349 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- PCNA | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 143/367 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PDZD2 | c.795G>T p.Q265H | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- PGBD1 | c.2205C>G p.C735W | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PGLYRP2 | c.96G>T p.Q32H | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); called by muse, mutect2
- PGR | c.305G>T p.S102I | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.09); called by mutect2, varscan2
- PHC3 | c.1589T>C p.I530T (on ENST00000494943 / NM_001308116.2; = p.I542T on NM_024947.4) | Missense Mutation (SNP) | VAF 188/356 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- PHF20 | c.2834A>T p.H945L | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- PHTF2 | c.865G>T p.G289C (on ENST00000248550 / NM_001366089.1; = p.G251C on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIGC | c.653A>T p.K218M | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- PIP4K2A | c.1175A>T p.Q392L | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- PKHD1 | c.1720G>T p.D574Y | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.125); called by muse, varscan2
- PKHD1L1 | c.3433G>T p.G1145W | Missense Mutation (SNP) | VAF 320/543 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- PLA2R1 | c.3193C>A p.P1065T | Missense Mutation (SNP) | VAF 88/236 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- PLCB1 | c.1618A>T p.M540L | Missense Mutation (SNP) | VAF 60/182 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- PLEC | c.12382G>C p.V4128L (on ENST00000322810 / NM_201380.4; = p.V4018L on NM_000445.5) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLEKHH2 | c.3941G>T p.R1314M | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- POLR1A | c.844G>T p.G282* | Nonsense Mutation (SNP) | VAF 46/111 reads (41%) | called by muse, mutect2, varscan2
- PRDM9 | c.1462A>G p.R488G | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRRC1 | c.187dup p.L63Pfs*42 | Frame Shift Ins (INS) | VAF 57/300 reads (19%) | called by pindel, varscan2
- PSD2 | c.971T>G p.L324R | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PSMC2 | c.475C>A p.P159T | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- PTPRS | c.3676A>T p.K1226* | Nonsense Mutation (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- PUDP | c.451G>T p.D151Y | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- RAPGEF3 | c.2066A>G p.Y689C (on ENST00000389212; = p.Y647C on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RASAL1 | c.2247C>G p.N749K | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RBM14 | c.487del p.D163Tfs*68 | Frame Shift Del (DEL) | VAF 13/70 reads (19%) | called by mutect2, pindel, varscan2
- RBM25 | c.1808A>T p.E603V | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RC3H2 | c.11A>T p.Q4L | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- REG3G | c.218C>A p.S73Y | Missense Mutation (SNP) | VAF 126/307 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- RELN | c.6835G>T p.E2279* | Nonsense Mutation (SNP) | VAF 56/158 reads (35%) | called by muse, varscan2
- RELN | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 29/82 reads (35%) | called by muse, mutect2, varscan2
- RGS7 | c.1206G>T p.K402N | Missense Mutation (SNP) | VAF 108/197 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- RNF144A | c.359_360del p.C120Sfs*59 | Frame Shift Del (DEL) | VAF 36/158 reads (23%) | called by pindel, varscan2
- RNF157 | c.649G>A p.V217I | Missense Mutation (SNP) | VAF 92/399 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ROBO3 | c.2015C>A p.A672D | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- ROBO4 | c.2565_2566delinsA p.L856Cfs*18 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | called by pindel, varscan2*
- ROBO4 | c.2250del p.I751Sfs*43 | Frame Shift Del (DEL) | VAF 13/97 reads (13%) | called by mutect2, pindel, varscan2
- ROCK1 | c.1565A>G p.Q522R | Missense Mutation (SNP) | VAF 125/547 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- RPN1 | c.1474C>G p.L492V | Missense Mutation (SNP) | VAF 41/259 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- RYR3 | c.3404G>T p.S1135I | Missense Mutation (SNP) | VAF 292/606 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.529); called by muse, mutect2
- RYR3 | c.3406G>T p.G1136W | Missense Mutation (SNP) | VAF 297/620 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2
- SASS6 | c.1438G>C p.E480Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- SCAF11 | c.3445G>A p.A1149T | Missense Mutation (SNP) | VAF 141/397 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCN3A | c.4086C>A p.Y1362* | Nonsense Mutation (SNP) | VAF 75/254 reads (30%) | called by muse, mutect2, varscan2
- SDR9C7 | c.721A>C p.I241L | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- SELPLG | c.380C>A p.A127E | Missense Mutation (SNP) | VAF 120/397 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- SERPING1 | c.590T>G p.L197R | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- SESTD1 | c.2005G>C p.A669P | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SEZ6L2 | c.2651A>G p.Y884C (on ENST00000308713 / NM_001114099.3; = p.Y827C on NM_012410.4) | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SF1 | c.539A>T p.K180I | Missense Mutation (SNP) | VAF 103/264 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SH3GL1 | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- SHANK2 | c.5108G>T p.G1703V | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.332); called by muse, mutect2
- SHLD1 | c.25G>T p.G9C | Missense Mutation (SNP) | VAF 105/257 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- SLC27A4 | c.86T>A p.L29Q | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- SLC3A1 | c.1253C>T p.T418I | Missense Mutation (SNP) | VAF 130/390 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- SLC6A1 | c.1598G>T p.G533V | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SLC6A12 | c.895del p.Q299Rfs*4 | Frame Shift Del (DEL) | VAF 38/113 reads (34%) | called by mutect2, pindel, varscan2
- SLC7A14 | c.1460C>A p.P487Q | Missense Mutation (SNP) | VAF 292/662 reads (44%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLCO1B1 | c.1147A>G p.I383V | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SMCHD1 | c.189A>T p.T63= | Splice Region (SNP) | VAF 29/43 reads (67%) | called by muse, mutect2, varscan2
- SNX25 | c.1527G>C p.M509I | Missense Mutation (SNP) | VAF 86/171 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SOGA3 | c.665C>A p.S222Y | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- SORCS1 | c.2219G>T p.G740V | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- SPANXB1 | c.53C>G p.S18C | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SPATA31A1 | c.3827A>T p.Q1276L | Missense Mutation (SNP) | VAF 106/247 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by mutect2, varscan2
- SPATA31E1 | c.1963C>G p.Q655E | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- SPATA5 | c.826G>C p.G276R | Missense Mutation (SNP) | VAF 66/118 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPTA1 | c.3650G>C p.S1217T | Missense Mutation (SNP) | VAF 71/282 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPTB | c.80A>G p.D27G | Missense Mutation (SNP) | VAF 160/341 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- STAT3 | c.583G>T p.V195L | Missense Mutation (SNP) | VAF 55/157 reads (35%) | SIFT tolerated (0.73); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- STAT5B | c.151C>A p.P51T | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- STXBP5 | c.3137G>A p.G1046E (on ENST00000321680 / NM_001127715.2; = p.G1010E on NM_139244.4) | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STXBP5L | c.2056G>T p.D686Y | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SV2C | c.1021C>A p.P341T | Missense Mutation (SNP) | VAF 224/417 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SYAP1 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- SYNE1 | c.18788C>A p.S6263* (on ENST00000367255 / NM_182961.4; = p.S6192* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 83/190 reads (44%) | called by muse, mutect2, varscan2
- SYNE1 | c.2971G>T p.E991* (on ENST00000367255 / NM_182961.4; = p.E998* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 77/215 reads (36%) | called by muse, mutect2, varscan2
- SYT17 | c.44C>G p.S15C | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.308); called by muse, varscan2
- SYT17 | c.125C>G p.S42* | Nonsense Mutation (SNP) | VAF 70/145 reads (48%) | called by muse, varscan2
- SYT2 | c.921C>A p.D307E | Missense Mutation (SNP) | VAF 123/403 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TACR1 | c.981C>A p.S327R | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- TDRD7 | c.3236_3237insATATTT p.T1079_D1080insYF | In Frame Ins (INS) | VAF 9/152 reads (6%) | called by muse*, mutect2, varscan2*
- TEPSIN | c.922G>T p.G308W | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- TESMIN | c.1431G>T p.K477N | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TET1 | c.6307C>T p.Q2103* | Nonsense Mutation (SNP) | VAF 22/123 reads (18%) | called by muse, mutect2, varscan2
- TJAP1 | c.1082G>T p.S361I (on ENST00000372445 / NM_001146016.1; = p.S351I on NM_080604.3) | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLK1 | c.1151G>T p.R384I | Missense Mutation (SNP) | VAF 108/374 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TLL2 | c.1063del p.L355Cfs*37 | Frame Shift Del (DEL) | VAF 33/81 reads (41%) | called by mutect2, pindel, varscan2
- TLR4 | c.536A>T p.H179L (on ENST00000355622 / NM_138554.5; = p.H139L on NM_003266.4) | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TMC5 | c.2537C>T p.T846I (on ENST00000396229 / NM_001105248.1; = p.T600I on NM_024780.5) | Missense Mutation (SNP) | VAF 26/217 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- TMEM132D | c.2617G>A p.D873N | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TMEM132D | c.893C>A p.T298N | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.165); called by muse, varscan2
- TMEM219 | c.300G>T p.R100S | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TMEM225 | c.125G>T p.R42I | Missense Mutation (SNP) | VAF 55/229 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- TMEM67 | c.1418A>T p.H473L | Missense Mutation (SNP) | VAF 30/294 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- TMPRSS11B | c.1043C>A p.T348K | Missense Mutation (SNP) | VAF 122/239 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TMPRSS11F | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 88/156 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- TMPRSS11F | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 86/154 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- TNKS2 | c.256G>T p.A86S | Missense Mutation (SNP) | VAF 80/317 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- TNNI1 | c.396C>A p.H132Q | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TOX | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 335/545 reads (61%) | SIFT tolerated (0.4); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TRAV8-3 | c.162G>T p.W54C | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRBV5-1 | c.314C>G p.S105W | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TRIM25 | c.41C>G p.S14C | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.585); called by muse, varscan2
- TRIM58 | c.821A>C p.K274T | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- TRIM75P | c.78del p.V27Sfs*48 | Frame Shift Del (DEL) | VAF 41/82 reads (50%) | called by mutect2, pindel, varscan2
- TRMT9B | c.37G>T p.V13L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRO | c.1306G>T p.A436S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0); called by mutect2, varscan2
- TRPM1 | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 69/123 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPM1 | c.425C>G p.T142R | Missense Mutation (SNP) | VAF 133/238 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- TSC22D1 | c.1793C>T p.S598F | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- TSPOAP1 | c.4991G>A p.G1664E | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TTN | c.97682T>C p.L32561S (on ENST00000591111; = p.L25137S on NM_003319.4) | Missense Mutation (SNP) | VAF 70/187 reads (37%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.79024G>C p.D26342H (on ENST00000591111; = p.D18918H on NM_003319.4) | Missense Mutation (SNP) | VAF 43/100 reads (43%) | PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- TTN | c.78661G>C p.E26221Q (on ENST00000591111; = p.E18797Q on NM_003319.4) | Missense Mutation (SNP) | VAF 56/142 reads (39%) | PolyPhen benign (0.33); called by muse, mutect2, varscan2
- TTN | c.37888C>G p.P12630A (on ENST00000591111; = p.P5206A on NM_003319.4) | Missense Mutation (SNP) | VAF 33/130 reads (25%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTN | c.10604A>C p.Q3535P (on ENST00000591111; = p.Q3489P on NM_003319.4) | Missense Mutation (SNP) | VAF 101/274 reads (37%) | called by muse, mutect2, varscan2
- TTN | c.10454C>T p.S3485F (on ENST00000591111; = p.S3439F on NM_003319.4) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
- TTN | c.3472G>A p.V1158I (on ENST00000591111; = p.V1112I on NM_003319.4) | Missense Mutation (SNP) | VAF 36/117 reads (31%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- U2SURP | c.1616G>A p.R539K | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- USH2A | c.4048T>A p.S1350T | Missense Mutation (SNP) | VAF 74/236 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- USH2A | c.3563C>A p.P1188H | Missense Mutation (SNP) | VAF 84/337 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- USP17L2 | c.329C>A p.S110Y | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- USP9X | c.1717A>G p.I573V | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- UTRN | c.8127G>C p.E2709D | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- VEZT | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 106/277 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- VIM | c.509G>T p.R170L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- VIP | c.476del p.G159Efs*10 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | called by mutect2, pindel, varscan2
- VNN2 | c.1046C>A p.T349K | Missense Mutation (SNP) | VAF 58/292 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- VSTM2L | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WBP2NL | c.254T>C p.V85A | Missense Mutation (SNP) | VAF 292/773 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- WDR1 | c.1513G>A p.A505T (on ENST00000382452; = p.A365T on NM_005112.5) | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- WDR36 | c.2845G>T p.A949S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- XKRX | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 87/163 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XPNPEP3 | c.710A>G p.Q237R | Missense Mutation (SNP) | VAF 94/435 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- XRN2 | c.283A>G p.R95G | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XXYLT1 | c.872G>T p.G291V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ZAN | c.1399C>A p.L467I | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- ZFHX4 | c.6435G>T p.R2145S | Missense Mutation (SNP) | VAF 38/52 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZFHX4 | c.7030del p.Q2344Kfs*48 | Frame Shift Del (DEL) | VAF 459/1035 reads (44%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.10827C>G p.I3609M | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZFP91 | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- ZMYND8 | c.277del p.V93Ffs*23 (on ENST00000311275 / NM_001363741.2; = p.V113Ffs*23 on NM_012408.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 62/251 reads (25%) | called by mutect2, pindel, varscan2
- ZNF37A | c.1051G>A p.G351R | Missense Mutation (SNP) | VAF 161/438 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ZNF521 | c.3085G>T p.V1029L | Missense Mutation (SNP) | VAF 69/216 reads (32%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF558 | c.681G>T p.L227F | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ZNF571 | c.1186T>C p.C396R | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF582 | c.1008G>C p.R336S | Missense Mutation (SNP) | VAF 131/316 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF610 | c.971A>T p.N324I | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ZNF99 | c.1947C>G p.Y649* | Nonsense Mutation (SNP) | VAF 23/98 reads (23%) | called by muse, mutect2, varscan2
- ZNRF4 | c.736C>G p.L246V | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZSCAN30 | c.342G>C p.E114D | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZSWIM2 | c.1244A>C p.H415P | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ABCA13 | c.10845G>T p.L3615= | Silent (SNP) | VAF 100/195 reads (51%) | called by muse, mutect2, varscan2
- ABCC6 | c.624A>C p.A208= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV99228102; called by mutect2, varscan2
- AC005833.1 | c.1078C>T p.L360= | Silent (SNP) | VAF 87/296 reads (29%) | called by muse, mutect2, varscan2
- ADAMTS7 | c.1020G>T p.L340= | Silent (SNP) | VAF 89/130 reads (68%) | called by muse, mutect2, varscan2
- ADCYAP1R1 | c.435C>T p.D145= | Silent (SNP) | VAF 45/98 reads (46%) | called by muse, mutect2, varscan2
- ADGRL1 | c.753C>A p.T251= (on ENST00000340736 / NM_001008701.3; = p.T246= on NM_014921.5) | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV100529271, COSV61564192; called by muse, mutect2, varscan2
- AFAP1L1 | c.1098G>T p.R366= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as rs1487276149; called by muse, mutect2, varscan2
- AKT1S1 | c.444C>T p.P148= (on ENST00000344175 / NM_001098633.4; = p.P168= on NM_032375.5) | Silent (SNP) | VAF 106/210 reads (50%) | catalogued as rs760629319; called by muse, mutect2, varscan2
- AL121899.2 | c.891G>C p.G297= | Silent (SNP) | VAF 68/428 reads (16%) | called by muse, varscan2
- ALDH5A1 | c.1521G>A p.V507= | Silent (SNP) | VAF 164/322 reads (51%) | called by muse, mutect2, varscan2
- AMER3 | c.1071C>T p.D357= | Silent (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2, varscan2
- ANO4 | c.2196A>T p.L732= (on ENST00000392977 / NM_001286615.2; = p.L697= on NM_178826.4) | Silent (SNP) | VAF 107/321 reads (33%) | called by muse, mutect2, varscan2
- APOB | c.1131C>A p.I377= | Silent (SNP) | VAF 40/117 reads (34%) | catalogued as COSV51946357; called by muse, mutect2, varscan2
- ATP2A1 | c.1824G>A p.T608= | Silent (SNP) | VAF 89/381 reads (23%) | catalogued as rs777310387, COSV62868321; called by muse, mutect2, varscan2
- BLK | c.883C>A p.R295= | Silent (SNP) | VAF 30/80 reads (38%) | called by muse, mutect2, varscan2
- C3 | c.3276C>G p.L1092= | Silent (SNP) | VAF 17/217 reads (8%) | called by muse, mutect2
- CACNA1C | c.4917T>C p.L1639= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as rs886049206; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CBX5 | c.243C>T p.P81= | Silent (SNP) | VAF 104/322 reads (32%) | called by muse, mutect2, varscan2
- CELSR2 | c.4143C>T p.R1381= | Silent (SNP) | VAF 26/42 reads (62%) | catalogued as rs767449979, COSV99604626; called by muse, mutect2, varscan2
- CFTR | c.3783G>A p.L1261= | Silent (SNP) | VAF 51/151 reads (34%) | called by muse, mutect2, varscan2
- CHRM3 | c.1737C>T p.V579= | Silent (SNP) | VAF 23/86 reads (27%) | catalogued as COSV99697197; called by muse, mutect2, varscan2
- CHST8 | c.9G>A p.L3= | Silent (SNP) | VAF 22/113 reads (19%) | called by muse, mutect2, varscan2
- CNMD | c.288C>T p.N96= | Silent (SNP) | VAF 64/258 reads (25%) | called by muse, mutect2, varscan2
- CPNE4 | c.828T>C p.N276= | Silent (SNP) | VAF 275/805 reads (34%) | catalogued as COSV70200460; called by muse, mutect2, varscan2
- CSMD3 | c.9015C>A p.V3005= (on ENST00000297405 / NM_001363185.1; = p.V2836= on NM_052900.3) | Silent (SNP) | VAF 7/84 reads (8%) | called by muse, mutect2
- CST2 | c.366C>A p.I122= | Silent (SNP) | VAF 45/138 reads (33%) | catalogued as rs142992719; called by muse, mutect2, varscan2
- CYP11A1 | c.564G>A p.K188= | Silent (SNP) | VAF 98/150 reads (65%) | catalogued as rs1325337548; called by muse, mutect2, varscan2
- DDX11 | c.1149C>A p.I383= | Silent (SNP) | VAF 22/121 reads (18%) | called by muse, mutect2, varscan2
- DSCAML1 | c.3600C>G p.G1200= (on ENST00000321322; = p.G1140= on NM_020693.4) | Silent (SNP) | VAF 24/140 reads (17%) | catalogued as COSV58398646; called by muse, mutect2
- EDC4 | c.4200C>T p.L1400= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs1160454028; called by muse, mutect2, varscan2
- EFHD1 | c.516G>T p.L172= | Silent (SNP) | VAF 38/111 reads (34%) | called by muse, mutect2, varscan2
- EIF4G1 | c.1920G>T p.V640= (on ENST00000346169 / NM_198241.3; = p.V444= on NM_004953.5) | Silent (SNP) | VAF 265/661 reads (40%) | called by muse, mutect2, varscan2
- ELL3 | c.628C>A p.R210= | Silent (SNP) | VAF 53/71 reads (75%) | catalogued as rs144962107; called by muse, mutect2, varscan2
- F10 | c.261C>G p.G87= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as COSV65021693; called by muse, mutect2, varscan2
- F5 | c.2538G>C p.G846= | Silent (SNP) | VAF 212/620 reads (34%) | called by muse, mutect2, varscan2
- FAM118B | c.837G>C p.R279= | Silent (SNP) | VAF 59/157 reads (38%) | called by muse, mutect2, varscan2
- FAT3 | c.1329T>C p.Y443= | Silent (SNP) | VAF 56/131 reads (43%) | called by muse, mutect2, varscan2
- FLG | c.2112A>C p.A704= | Silent (SNP) | VAF 208/705 reads (30%) | called by muse, mutect2, varscan2
- FRY | c.4269G>T p.T1423= | Silent (SNP) | VAF 52/270 reads (19%) | called by muse, mutect2, varscan2
- G6PC2 | c.366C>A p.V122= | Silent (SNP) | VAF 439/1352 reads (32%) | called by muse, mutect2, varscan2
- GPR61 | c.681C>A p.V227= | Silent (SNP) | VAF 40/148 reads (27%) | called by muse, varscan2
- GPRIN3 | c.588G>A p.Q196= | Silent (SNP) | VAF 30/129 reads (23%) | called by muse, mutect2, varscan2
- GPRIN3 | c.504G>A p.E168= | Silent (SNP) | VAF 34/241 reads (14%) | called by muse, mutect2, varscan2
- GRIK5 | c.666C>T p.I222= | Silent (SNP) | VAF 145/640 reads (23%) | called by muse, mutect2, varscan2
- H2BC4 | c.66G>T p.A22= | Silent (SNP) | VAF 94/182 reads (52%) | called by muse, mutect2, varscan2
- HDAC3 | c.495C>G p.L165= | Silent (SNP) | VAF 50/136 reads (37%) | called by muse, mutect2, varscan2
- HS3ST4 | c.1107C>A p.A369= | Silent (SNP) | VAF 43/154 reads (28%) | called by muse, mutect2, varscan2
- HTR4 | c.363C>T p.A121= | Silent (SNP) | VAF 32/115 reads (28%) | called by muse, mutect2, varscan2
- ICE1 | c.4884G>A p.V1628= | Silent (SNP) | VAF 16/190 reads (8%) | called by muse, mutect2
- ITIH2 | c.1680C>A p.A560= | Silent (SNP) | VAF 65/217 reads (30%) | catalogued as COSV100623377; called by muse, mutect2, varscan2
- KCNJ3 | c.804C>T p.L268= | Silent (SNP) | VAF 96/215 reads (45%) | called by muse, mutect2, varscan2
- KCNMB4 | c.288T>C p.S96= | Silent (SNP) | VAF 21/118 reads (18%) | catalogued as rs776418718; called by muse, mutect2, varscan2
- KDELR3 | c.30G>T p.L10= | Silent (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2, varscan2
- KIAA0232 | c.1686G>T p.G562= | Silent (SNP) | VAF 94/217 reads (43%) | called by muse, mutect2, varscan2
- KIAA0319 | c.3174C>T p.S1058= | Silent (SNP) | VAF 61/399 reads (15%) | catalogued as rs1025797957; called by muse, mutect2, varscan2
- KLHDC7A | c.1413C>T p.I471= | Silent (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- KRTAP19-4 | c.189G>T p.L63= | Silent (SNP) | VAF 55/129 reads (43%) | catalogued as COSV61858720; called by muse, mutect2, varscan2
- LILRB4 | c.1224C>A p.P408= (on ENST00000391733 / NM_001278428.3; = p.P407= on NM_001278426.3) | Silent (SNP) | VAF 106/191 reads (55%) | called by muse, mutect2, varscan2
- LRFN2 | c.606G>T p.L202= | Silent (SNP) | VAF 38/73 reads (52%) | called by muse, mutect2, varscan2
- LRRC18 | c.714C>A p.P238= | Silent (SNP) | VAF 97/288 reads (34%) | catalogued as COSV53286279; called by muse, mutect2, varscan2
- LRRC4B | c.390C>T p.F130= | Silent (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- MARCHF10 | c.693G>A p.L231= | Silent (SNP) | VAF 131/339 reads (39%) | called by muse, mutect2, varscan2
- MB21D2 | c.453G>T p.R151= | Silent (SNP) | VAF 70/180 reads (39%) | catalogued as COSV101164979; called by muse, mutect2, varscan2
- MICAL2 | c.486A>G p.L162= | Silent (SNP) | VAF 213/320 reads (67%) | called by muse, mutect2, varscan2
- MMP9 | c.738C>A p.T246= | Silent (SNP) | VAF 68/229 reads (30%) | called by muse, mutect2, varscan2
- MROH1 | c.330G>T p.A110= | Silent (SNP) | VAF 37/63 reads (59%) | catalogued as COSV58193275; called by muse, mutect2, varscan2
- MUC16 | c.11742G>A p.L3914= | Silent (SNP) | VAF 12/134 reads (9%) | called by mutect2, varscan2
- MUL1 | c.498C>T p.F166= | Silent (SNP) | VAF 40/159 reads (25%) | called by muse, mutect2, varscan2
- MYO10 | c.3231G>A p.Q1077= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV57029264; called by muse, mutect2
- MYO18B | c.5460C>A p.T1820= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV59141393; called by muse, mutect2, varscan2
- MYO5A | c.2334A>T p.R778= | Silent (SNP) | VAF 47/62 reads (76%) | called by muse, mutect2, varscan2
- MYT1L | c.2958G>C p.G986= | Silent (SNP) | VAF 14/75 reads (19%) | called by muse, mutect2, varscan2
- NBEA | c.7806G>T p.V2602= | Silent (SNP) | VAF 113/303 reads (37%) | called by muse, mutect2, varscan2
- NLRP3 | c.24G>T p.L8= | Silent (SNP) | VAF 47/156 reads (30%) | called by muse, mutect2, varscan2
- NLRP8 | c.1974G>C p.V658= | Silent (SNP) | VAF 124/279 reads (44%) | called by muse, mutect2, varscan2
- NOP53 | c.1284C>G p.L428= | Silent (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- OLFML2B | c.1875C>T p.D625= | Silent (SNP) | VAF 58/165 reads (35%) | catalogued as rs1379795545, COSV54195135, COSV54195746; called by muse, mutect2, varscan2
- OOEP | c.318G>A p.V106= | Silent (SNP) | VAF 100/211 reads (47%) | called by muse, mutect2, varscan2
- OR10J3 | c.144C>T p.T48= | Silent (SNP) | VAF 337/906 reads (37%) | called by muse, mutect2, varscan2
- OR11H1 | c.234C>A p.V78= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as rs1342795244, COSV99421999; called by mutect2, varscan2
- OR2W3 | c.201C>T p.S67= | Silent (SNP) | VAF 132/521 reads (25%) | called by muse, mutect2, varscan2
- OR4C11 | c.339C>A p.L113= | Silent (SNP) | VAF 80/194 reads (41%) | called by muse, mutect2, varscan2
- OR4C46 | c.711C>A p.T237= | Silent (SNP) | VAF 104/172 reads (60%) | called by muse, mutect2, varscan2
- OR51E1 | c.954C>A p.P318= | Silent (SNP) | VAF 183/328 reads (56%) | catalogued as COSV67809350; called by muse, mutect2, varscan2
- OR5AS1 | c.396T>C p.Y132= | Silent (SNP) | VAF 37/185 reads (20%) | called by muse, mutect2, varscan2
- OR5T3 | c.426C>G p.L142= | Silent (SNP) | VAF 195/406 reads (48%) | called by muse, mutect2, varscan2
- OR8B4 | c.546C>A p.P182= | Silent (SNP) | VAF 66/97 reads (68%) | catalogued as COSV62069226, COSV62069437; called by muse, mutect2, varscan2
- OR8B8 | c.579T>C p.Y193= | Silent (SNP) | VAF 288/537 reads (54%) | catalogued as rs1339861249, COSV60145779; called by muse, mutect2, varscan2
- OR8J1 | c.630C>A p.S210= | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as COSV57320361; called by muse, mutect2, varscan2
- OSBPL7 | c.1407G>T p.A469= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- OTOA | c.2394C>A p.P798= (on ENST00000286149; = p.P784= on NM_144672.4) | Silent (SNP) | VAF 105/271 reads (39%) | catalogued as COSV99623637; called by muse, mutect2, varscan2
- PAX4 | c.234G>C p.R78= | Silent (SNP) | VAF 130/362 reads (36%) | called by muse, mutect2, varscan2
- PCDHA3 | c.1785C>T p.R595= | Silent (SNP) | VAF 41/104 reads (39%) | catalogued as COSV63546562; called by muse, mutect2, varscan2
- PCDHB13 | c.966A>G p.A322= | Silent (SNP) | VAF 127/349 reads (36%) | catalogued as rs746460308; called by muse, mutect2, varscan2
- PCLO | c.2142C>T p.G714= | Silent (SNP) | VAF 18/208 reads (9%) | catalogued as rs1304702122; called by muse, mutect2
- PDP2 | c.1209G>A p.Q403= | Silent (SNP) | VAF 61/167 reads (37%) | called by muse, mutect2, varscan2
- PIK3AP1 | c.948C>G p.L316= | Silent (SNP) | VAF 86/138 reads (62%) | called by muse, mutect2, varscan2
- PLEKHA7 | c.1770A>T p.P590= | Silent (SNP) | VAF 28/57 reads (49%) | called by muse, mutect2, varscan2
- POPDC2 | c.999T>C p.S333= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as rs370632589; called by muse, mutect2, varscan2
- PPRC1 | c.2064C>T p.S688= | Silent (SNP) | VAF 14/110 reads (13%) | called by muse, mutect2
- PRLR | c.771T>A p.A257= | Silent (SNP) | VAF 138/430 reads (32%) | called by muse, mutect2, varscan2
- PRR30 | c.894C>T p.F298= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs549018789; called by muse, mutect2, varscan2
- PTPRC | c.1560G>A p.L520= | Silent (SNP) | VAF 47/170 reads (28%) | called by muse, mutect2, varscan2
- PXDNL | c.1509G>T p.L503= | Silent (SNP) | VAF 363/618 reads (59%) | called by muse, mutect2, varscan2
- RARRES1 | c.381T>G p.S127= | Silent (SNP) | VAF 60/511 reads (12%) | called by muse, mutect2, varscan2
- RAVER1 | c.609C>T p.L203= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV99348839; called by muse, mutect2, varscan2
- RBMXL1 | c.1008A>T p.S336= | Silent (SNP) | VAF 208/418 reads (50%) | called by muse, varscan2
- RIMS2 | c.4371C>T p.I1457= (on ENST00000666250 / NM_001348490.2; = p.I1028= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 82/205 reads (40%) | catalogued as COSV51656680; called by muse, mutect2, varscan2
- RNASE2 | c.168C>A p.V56= | Silent (SNP) | VAF 43/83 reads (52%) | catalogued as rs200694912; called by muse, mutect2, varscan2
- RXFP2 | c.2043A>T p.P681= | Silent (SNP) | VAF 32/150 reads (21%) | called by muse, mutect2, varscan2
- RYR3 | c.1300C>T p.L434= | Silent (SNP) | VAF 73/185 reads (39%) | catalogued as rs756987758; called by muse, mutect2, varscan2
- SAMD9L | c.4602C>A p.I1534= | Silent (SNP) | VAF 75/268 reads (28%) | called by muse, mutect2, varscan2
- SCG2 | c.1188G>A p.E396= | Silent (SNP) | VAF 53/251 reads (21%) | catalogued as rs908820925; called by muse, mutect2, varscan2
- SEMA5A | c.142C>A p.R48= | Silent (SNP) | VAF 66/212 reads (31%) | called by muse, mutect2, varscan2
- SENP7 | c.1944A>G p.E648= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as rs755830593; called by muse, mutect2, varscan2
- SGCE | c.1194T>C p.S398= (on ENST00000647096; = p.S362= on NM_003919.3) | Silent (SNP) | VAF 27/74 reads (36%) | called by muse, mutect2, varscan2
- SLC12A7 | c.639G>T p.G213= | Silent (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- SLC17A8 | c.1593G>A p.E531= | Silent (SNP) | VAF 21/80 reads (26%) | called by muse, mutect2, varscan2
- SLC2A2 | c.330T>A p.T110= | Silent (SNP) | VAF 14/386 reads (4%) | called by muse, mutect2
- SLCO1B1 | c.1260C>A p.S420= | Silent (SNP) | VAF 30/110 reads (27%) | catalogued as COSV99918426; called by muse, varscan2
- SLIT3 | c.408C>T p.T136= | Silent (SNP) | VAF 79/246 reads (32%) | catalogued as rs758379745; called by muse, mutect2, varscan2
- SOD2 | c.93G>A p.L31= | Silent (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- SPIRE1 | c.741G>A p.K247= | Silent (SNP) | VAF 67/117 reads (57%) | called by muse, mutect2, varscan2
- SPTBN4 | c.5406G>T p.A1802= | Silent (SNP) | VAF 21/59 reads (36%) | called by muse, mutect2, varscan2
- ST8SIA6 | c.1035C>A p.P345= | Silent (SNP) | VAF 86/309 reads (28%) | called by muse, mutect2, varscan2
- STAT6 | c.207A>G p.G69= | Silent (SNP) | VAF 28/120 reads (23%) | called by muse, mutect2, varscan2
- SYT1 | c.558G>A p.L186= | Silent (SNP) | VAF 52/156 reads (33%) | catalogued as rs1299460181, COSV54031299; called by muse, mutect2, varscan2
- SYTL5 | c.168T>A p.T56= | Silent (SNP) | VAF 31/38 reads (82%) | called by muse, mutect2, varscan2
- TBC1D9B | c.2094G>T p.V698= | Silent (SNP) | VAF 21/77 reads (27%) | called by muse, mutect2, varscan2
- TECRL | c.495C>A p.I165= | Silent (SNP) | VAF 24/53 reads (45%) | called by muse, mutect2, varscan2
- THRA | c.1170C>A p.G390= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs372962433; called by muse, mutect2, varscan2
- TLCD3B | c.423G>T p.L141= | Silent (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- TMEM132D | c.894C>A p.T298= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as COSV70602152; called by muse, varscan2
- TMEM53 | c.324C>T p.L108= | Silent (SNP) | VAF 10/172 reads (6%) | catalogued as COSV62409240; called by muse, mutect2
- TRAPPC9 | c.2673C>G p.T891= | Silent (SNP) | VAF 145/287 reads (51%) | called by muse, mutect2, varscan2
- TRIM3 | c.813C>T p.R271= | Silent (SNP) | VAF 68/126 reads (54%) | catalogued as rs557450092; called by muse, mutect2, varscan2
- TRIM55 | c.792A>G p.S264= | Silent (SNP) | VAF 196/401 reads (49%) | called by muse, mutect2, varscan2
- TSHR | c.426T>A p.P142= | Silent (SNP) | VAF 65/123 reads (53%) | called by muse, mutect2, varscan2
27 further variants in this file (0 protein-altering or splice-affecting, 8 silent, 19 other) are not listed here.
